Somatic mutation profile of tumor specimen TARGET-10-PAREZM-09A (aliquot TARGET-10-PAREZM-09A-01D) from TARGET case TARGET-10-PAREZM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,130 days).
Specimen TARGET-10-PAREZM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a378e75a-5fdb-4fb1-8c69-267aeac28c08.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREZM-10A (Blood Derived Normal), aliquot TARGET-10-PAREZM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7ab836c-a3ac-4672-995f-550e57eb2431

The open-access MAF lists 19 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 4, RNA 1, 3'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLRG1 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99868396; called by muse, mutect2, varscan2
- SCN2A | c.5704C>T p.R1902C | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs367833365, CM034570; called by muse, mutect2, varscan2
- SMAD9 | c.1048G>T p.V350L (on ENST00000379826 / NM_001127217.3; = p.V313L on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs757281925, COSV63204714; called by mutect2, varscan2
- TBC1D2B | c.2435G>T p.R812L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56042778; called by muse, varscan2
- USH2A | c.1703A>G p.Y568C | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1275811314; called by muse, mutect2, varscan2
- C8orf89 | c.364G>T p.G122* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- FOXRED1 | c.272C>A p.A91D | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- GTF3C1 | c.4597G>T p.A1533S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2
- LAMP1 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 3/21 reads (14%) | called by muse, varscan2
- WEE2 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 3/16 reads (19%) | called by muse, varscan2
- EBLN1 | c.732G>T p.L244= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- GLB1L3 | c.819C>T p.A273= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs575973887; called by mutect2, varscan2
- PSG9 | c.699G>T p.L233= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- SARDH | c.618G>A p.P206= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs371726703; called by muse, mutect2
- TRHR | c.441C>T p.I147= | Silent (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846171 G>A | 5'Flank (SNP) | VAF 3/17 reads (18%) | catalogued as rs1369647499; called by muse, mutect2, varscan2
- CEP41 | c.*1170G>T | 3'UTR (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- CMAHP | n.1051G>T | RNA (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2, varscan2
- EPS8 | c.1101+64C>G | Intron (SNP) | VAF 50/111 reads (45%) | called by muse, mutect2
